Gene-level copy-number profile of tumor specimen TCGA-E6-A1LZ-01A from TCGA case TCGA-E6-A1LZ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 76.8 years (28,054 days).
Specimen TCGA-E6-A1LZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.32496629-22b4-4ba7-9f7b-454475783f77.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-E6-A1LZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/41299e31-ff94-4210-9dbb-a74460ca7ff2

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 289; copy number 2: 15,881; copy number 3: 22,790; copy number 4: 10,059; copy number 5: 2,823; copy number 6: 4,814; copy number 7: 1,440; copy number 8: 636; copy number 9: 76; copy number 11: 691; copy number 12: 150; copy number 15: 15; copy number 16: 99; copy number 17: 11; copy number 19: 38.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-E6-A1LZ-01A-11D-A141-01): tumor purity 0.56, ploidy 3.36, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,156 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–161,964,070, 851 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr1:162,039,016–177,437,880, 302 genes, copy number 7 (broad region; genes not listed).
- chr3:129,314,771–141,615,344, 222 genes, copy number 7 (broad region; genes not listed).
- chr3:169,003,022–198,222,513, 589 genes, copy number 9–11 (broad region; genes not listed).
- chr6:66,710,242–67,210,480, 3 genes, copy number 7: AL450336.1, RNU7-66P, AL591004.1.
- chr12:12,850,982–12,917,937, 3 genes, copy number 7 (within-gene range 4–7): AC007688.2, RPL13AP20, GPRC5A.
- chr12:41,658,676–48,570,066, 158 genes, copy number 7–12 (broad region; genes not listed).
- chr12:53,506,688–53,625,979, 1 gene, copy number 17 (within-gene range 6–17): ATF7-NPFF.
- chr12:53,507,856–53,626,410, 1 gene, copy number 17 (within-gene range 6–17): ATF7.
- chr12:53,531,752–56,237,846, 156 genes, copy number 11–19 (broad region; genes not listed).
- chr17:37,686,431–40,885,242, 144 genes, copy number 8–16 (broad region; genes not listed).
- chr17:41,549,606–42,440,259, 45 genes, copy number 8: LINC00974, KRT9, KRT14, KRT16, KRT17, KRT42P, AC130686.1, EIF1, GAST, HAP1, RNA5SP442, RN7SL399P, JUP, P3H4, FKBP10, NT5C3B, KLHL10, AC125257.1, KLHL11, ACLY, AC125257.2, TTC25, CNP, DNAJC7, NKIRAS2, ZNF385C, C17orf113, DHX58, KAT2A, AC099811.2, HSPB9, RAB5C, AC099811.3, KCNH4, HCRT, GHDC, STAT5B, AC099811.6, AC099811.4, AC099811.1, AC099811.5, STAT5A, STAT3, CAVIN1, RNU7-97P.
- chr18:47,390–15,330,282, 376 genes, copy number 8 (broad region; genes not listed).
- chr18:21,529,284–29,048,719, 131 genes, copy number 7–11 (broad region; genes not listed).
- chr19:10,718,079–10,833,488, 1 gene, copy number 15 (within-gene range 2–15): DNM2.
- chr19:10,780,254–11,133,820, 14 genes, copy number 15 (within-gene range 3–15): MIR4748, MIR199A1, MIR6793, TMED1, C19orf38, HIKESHIP2, CARM1, YIPF2, TIMM29, SMARCA4, AC011442.1, RN7SL192P, AC006127.1, LDLR.
- chr19:23,525,631–34,066,283, 159 genes, copy number 8–11 (within-gene range 3–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 289. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
